Gene-level copy-number profile of tumor specimen TARGET-40-PASSLM-01A from TARGET case TARGET-40-PASSLM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 9.7 years (3,538 days).
Specimen TARGET-40-PASSLM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c63f1c6d-d974-556b-9873-c393e0de54c0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASSLM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 422 have no estimate.
https://portal.gdc.cancer.gov/files/5ddbb04f-9c88-4a59-b279-0a9380e0d387

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,019; copy number 2: 11,468; copy number 3: 22,308; copy number 4: 19,282; copy number 5: 4,187; copy number 6: 880; copy number 7: 659; copy number 8: 115; copy number 9: 204; copy number 10: 35; copy number 11: 5; copy number 12: 14; copy number 13: 2; copy number 27: 2.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,782,805–165,783,134, 1 gene: AC008562.1.
- chr7:65,269,374–65,463,438, 6 genes: AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3.
- chr7:78,134,079–78,170,915, 2 genes: AC004808.2, AC004808.1.
- chr7:147,146,342–147,167,572, 2 genes: DUTP3, RANP2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,034 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:95,477,164–99,322,741, 121 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr2:116,726,453–116,818,761, 3 genes, copy number 7: AC062016.1, MTCYBP39, AC062016.2.
- chr2:133,333,829–133,596,399, 5 genes, copy number 11: RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93.
- chr6:17,224,243–17,707,344, 11 genes, copy number 7: AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1.
- chr6:19,323,428–19,839,080, 1 gene, copy number 8 (within-gene range 6–8): LNC-LBCS.
- chr6:19,438,283–24,646,191, 57 genes, copy number 8: RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43.
- chr6:26,198,784–28,137,293, 113 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:37,433,219–39,229,475, 31 genes, copy number 9–12 (within-gene range 6–12): CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5.
- chr7:77,038–81,178, 1 gene, copy number 8: AC093627.6.
- chr7:151,556,124–158,587,823, 104 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr7:158,532,718–159,233,377, 14 genes, copy number 7: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr10:19,290,223–19,291,480, 1 gene, copy number 7: AL590378.1.
- chr10:19,816,239–20,351,100, 4 genes, copy number 7 (within-gene range 4–7): PLXDC2, AC069549.1, AC069549.2, AMD1P1.
- chr10:22,693,953–23,393,467, 13 genes, copy number 7: AL390318.1, RNU6-413P, ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2.
- chr10:50,990,888–52,298,423, 1 gene, copy number 9 (within-gene range 4–15): PRKG1.
- chr10:51,695,486–53,766,614, 14 genes, copy number 7–13: CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:54,452,423–54,452,511, 1 gene, copy number 13: RNU6-687P.
- chr10:89,978,717–89,979,070, 1 gene, copy number 12: SNRPD2P1.
- chr10:112,446,998–113,167,678, 11 genes, copy number 9 (within-gene range 5–9): VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30.
- chr13:43,023,203–43,159,466, 2 genes, copy number 7: DNAJC15, LINC00400.
- chr16:76,107,283–77,756,681, 26 genes, copy number 7: AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3.
- chr16:80,040,662–80,045,745, 1 gene, copy number 9: AC092130.1.
- chr20:1,561,385–1,620,061, 2 genes, copy number 27 (within-gene range 3–27): SIRPB1, AL049634.3.
- chr21:18,561,265–18,760,320, 1 gene, copy number 7 (within-gene range 4–7): MIR548XHG.
- chr21:18,686,090–36,294,274, 310 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr21:38,812,878–38,956,467, 1 gene, copy number 7 (within-gene range 6–7): AP001042.1.
- chr21:38,888,772–44,711,572, 184 genes, copy number 7 (within-gene range 7–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 178. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
